MMRF case MMRF_2102 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/89971fcb-f73d-410b-bf41-d3de13cc1306

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 76 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 76.3 years (27,884 days); ISS stage: III; Days to last known disease status: 969 days (2.7 years); Days to last follow up: 969 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 379 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 711 days (1.9 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 717 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 6.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1446 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.07 mg/dL; Immunoglobulin G 80 g/L; Immunoglobulin A 0.178 g/L; Immunoglobulin M 0.165 g/L; Beta 2 Microglobulin 5.59 µg/mL; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 8.57 ×10⁹/L; Absolute Neutrophil 4.13 ×10⁹/L; Platelets 321 ×10⁹/L; Creatinine 149 µmol/L; Calcium 2.38 mmol/L; Albumin 29 g/L; Total Protein 12.5 g/dL; Glucose 7.92 mmol/L; C-Reactive Protein 1.18 mg/dL.
- Day 85 (ECOG 1): M Protein 1.56 g/dL; Immunoglobulin G 23.5 g/L; Immunoglobulin A 0.113 g/L; Immunoglobulin M 0.213 g/L; Beta 2 Microglobulin 3.02 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 7.96 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 109 µmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 11.8 mmol/L.
- Day 169 (ECOG 1): M Protein 0.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.513 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.151 g/L; Immunoglobulin M 0.194 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 3.34 ×10⁹/L; Absolute Neutrophil 1.57 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L.
- Day 267 (ECOG 1): M Protein 1.04 g/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.163 g/L; Immunoglobulin M 0.269 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.42 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 111 µmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.5 g/dL; Glucose 4.51 mmol/L.
- Day 351 (ECOG 1): M Protein 1.03 g/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.0103 g/L; Immunoglobulin M 0.252 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 2.96 ×10⁹/L; Absolute Neutrophil 1.36 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 81.3 µmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 6.93 mmol/L.
- Day 407 (ECOG 1): M Protein 1.06 g/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 0.186 g/L; Immunoglobulin M 0.266 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.31 ×10⁹/L; Absolute Neutrophil 2.67 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 85.7 µmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 6.55 mmol/L.
- Day 547 (ECOG 1): M Protein 1.24 g/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 0.251 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.73 ×10⁹/L; Absolute Neutrophil 1.85 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 90.2 µmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7.29 g/dL; Glucose 6.93 mmol/L.
- Day 631 (ECOG 1): M Protein 1.99 g/dL; Immunoglobulin G 24.4 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.67 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.43 mmol/L; Albumin 45.7 g/L; Total Protein 8.8 g/dL; Glucose 7.04 mmol/L.
- Day 717 (ECOG 2): M Protein 5.21 g/dL; Immunoglobulin G 76.2 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.09 ×10⁹/L; Absolute Neutrophil 1.72 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 109 µmol/L; Calcium 2.48 mmol/L; Albumin 32 g/L; Total Protein 12 g/dL; Glucose 5.94 mmol/L.
- Day 797 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.473 mg/dL; Immunoglobulin G 3.64 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.63 ×10⁹/L; Absolute Neutrophil 0.87 ×10⁹/L; Platelets 69.6 ×10⁹/L.
- Day 878 (ECOG 1): M Protein 0.15 g/dL; Immunoglobulin G 4.17 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 2.81 ×10⁹/L; Absolute Neutrophil 0.45 ×10⁹/L; Platelets 53.6 ×10⁹/L; Creatinine 69 µmol/L; Calcium 2.18 mmol/L; Albumin 38.5 g/L; Total Protein 5.6 g/dL; Glucose 7.21 mmol/L.
- Day 969 (ECOG 1): M Protein 0.2 g/dL; Immunoglobulin G 5.22 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.34 ×10⁹/L; Absolute Neutrophil 1.11 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.25 mmol/L; Albumin 39.9 g/L; Total Protein 5.9 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -17: Weight: 75 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2102_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_2102_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
